CCDI case PBCKIK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/23b01c80-60eb-49c9-ab6f-0e77b03796e8

Demographics
Sex at birth: female.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 1.1 years (417 days).

Biospecimens (3 samples)
- Sample 0DTYAP: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DTYAZ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DTYBA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
